Gene-level copy-number profile of tumor specimen ALCH-B1JM-TTP1-A from ALCHEMIST case ALCH-B1JM, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Non-small cell carcinoma; Age at diagnosis: 80.4 years (29,358 days).
Specimen ALCH-B1JM-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f97e9f70-0a5d-43f0-8394-a3bebb11c08a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1JM-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/d47ed1c1-681c-4fd8-b8ad-90a2bfa7cd37

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 28; copy number 1: 5,177; copy number 2: 53,628; copy number 3: 53; copy number 4: 15; copy number 5: 7; copy number 22: 2.

Homozygous deletions (total copy number 0; autosomes only): 26 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:37,784,191–37,844,896, 1 gene (within-gene range 0–2): ADGRA2.
- chr11:72,754,729–72,814,054, 4 genes (within-gene range 0–2): STARD10, Y_RNA, MIR4692, AP002381.2.
- chr16:67,175,599–67,227,048, 7 genes (within-gene range 0–2): KIAA0895L, EXOC3L1, E2F4, ELMO3, MIR328, AC040160.2, LRRC29.
- chr16:89,873,570–89,938,761, 6 genes: TCF25, AC092143.3, MC1R, AC092143.1, AC092143.2, TUBB3.
- chr18:37,473,330–37,473,977, 1 gene (within-gene range 0–2): AC129908.1.
- chr22:37,943,050–37,953,669, 3 genes (within-gene range 0–1): AL031587.5, C22orf23, AL031587.3.
- chr22:37,967,563–37,987,422, 2 genes (within-gene range 0–1): MIR6820, SOX10.
- chr22:41,244,779–41,286,187, 2 genes: RANGAP1, MIR6889.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:1,947,278–1,989,920, 2 genes, copy number 22: MRPL23, MRPL23-AS1.
- chr21:10,482,738–13,016,692, 7 genes, copy number 5 (within-gene range 2–5): AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1.

Autosomal genes at a single copy (total copy number 1): 2,323. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
